Somatic mutation profile of tumor specimen TCGA-55-7913-01B (aliquot TCGA-55-7913-01B-11D-2238-08) from TCGA case TCGA-55-7913, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 61.1 years (22,326 days).
Specimen TCGA-55-7913-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22154f9d-6517-4fa0-9d64-de75bccc0d0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7913-10A (Blood Derived Normal), aliquot TCGA-55-7913-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2a5eafe-27be-4d43-b8e6-8a6af772841f

The open-access MAF lists 362 somatic variants for this specimen: 275 protein-altering or splice-affecting, 78 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 240, Silent 78, Nonsense Mutation 18, Frame Shift Del 8, Splice Region 5, Splice Site 4, Intron 3, RNA 2, 3'Flank 2, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 54/117 reads (46%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12879G>T p.L4293F | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.153); catalogued as COSV101291298, COSV68950147; called by muse, mutect2
- ACSF2 | c.960G>C p.M320I | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV99366143; called by muse, mutect2, varscan2
- ADAMTS16 | c.1851-2A>G p.X617_splice | Splice Site (SNP) | VAF 27/88 reads (31%) | catalogued as COSV99940846; called by muse, mutect2, varscan2
- ADAMTS7 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101183083; called by muse, mutect2, varscan2
- AGK | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV100814597; called by muse, varscan2
- AKAP17A | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 67/297 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100002124, COSV58308078; called by muse, mutect2, varscan2
- ANKRD17 | c.4945A>T p.S1649C | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV100428942; called by muse, mutect2, varscan2
- AP5Z1 | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV100804089; called by muse, mutect2, varscan2
- APEX1 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.455); catalogued as COSV99164464; called by muse, mutect2, varscan2
- ASMT | c.70-2A>T p.X24_splice | Splice Site (SNP) | VAF 12/104 reads (12%) | catalogued as COSV101172438; called by muse, mutect2, varscan2
- ASPM | c.7587A>T p.R2529S | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.065); catalogued as COSV99660105; called by muse, mutect2, varscan2
- ASPSCR1 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV100142389; called by muse, mutect2, varscan2
- ATP12A | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99517384; called by muse, mutect2, varscan2
- ATP8A2 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99681365; called by mutect2, varscan2
- ATXN1 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1001944475, COSV99786031; called by muse, mutect2, varscan2
- B4GALT2 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1312790665, COSV100530561; called by muse, mutect2, varscan2
- BANP | c.737G>T p.R246L (on ENST00000286122; = p.R215L on NM_017869.4) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53740801, COSV99621365; called by muse, mutect2
- BEND2 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.637); catalogued as COSV101191950; called by muse, mutect2, varscan2
- BEST3 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1004584936, COSV100437714; called by muse, mutect2, varscan2
- BICC1 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100874821; called by muse, mutect2, varscan2
- BNIP5 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV101465142; called by muse, varscan2
- BPI | c.1103C>A p.P368H (on ENST00000262865; = p.P364H on NM_001725.3) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99480561; called by muse, mutect2, varscan2
- BPI | c.1327C>A p.L443I (on ENST00000262865; = p.L439I on NM_001725.3) | Missense Mutation (SNP) | VAF 73/326 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.011); catalogued as COSV99480564; called by muse, mutect2, varscan2
- C16orf46 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100215252, COSV55151225; called by muse, mutect2, varscan2
- C1orf87 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100967017; called by muse, mutect2, varscan2
- C5AR1 | c.1013C>A p.S338Y | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100754001; called by muse, mutect2, varscan2
- CACNA1C | c.6076C>A p.P2026T (on ENST00000399634 / NM_001167625.1; = p.P1955T on NM_000719.7) | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100217804; called by muse, mutect2, varscan2
- CACNA1E | c.6488C>G p.P2163R (on ENST00000367573 / NM_001205293.3; = p.P2120R on NM_000721.4) | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62390404; called by muse, mutect2
- CADPS | c.2426C>T p.A809V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99337412; called by muse, mutect2, varscan2
- CAPN13 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV99700072; called by muse, mutect2, varscan2
- CASQ2 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99797359; called by muse, mutect2, varscan2
- CCBE1 | c.1115A>G p.Q372R | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.366); catalogued as COSV101232809; called by muse, mutect2, varscan2
- CCDC63 | c.1013C>A p.T338K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.061); catalogued as COSV57528902; called by muse, mutect2, varscan2
- CCDC68 | c.428A>T p.E143V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100491728; called by muse, mutect2, varscan2
- CD93 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV99849111; called by muse, mutect2, varscan2
- CDH10 | c.2183C>A p.P728H | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52604247; called by muse, mutect2
- CDH6 | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV99418764; called by muse, mutect2
- CDX4 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100999128; called by muse, mutect2, varscan2
- CEACAM8 | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99747550; called by muse, mutect2, varscan2
- CELSR2 | c.5911G>T p.V1971L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99603616; called by muse, mutect2, varscan2
- CEP131 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.768); catalogued as COSV99488101; called by muse, mutect2, varscan2
- CEP192 | c.5266C>T p.P1756S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV100381027; called by muse, mutect2, varscan2
- CEP97 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs766672640, COSV100511664; called by muse, mutect2, varscan2
- CFAP94 | c.1879A>T p.R627W (on ENST00000320267 / NM_001352064.2; = p.R633W on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100209201; called by mutect2, varscan2
- CIAPIN1 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV101275876, COSV67953565; called by muse, mutect2, varscan2
- CLDN22 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV100032859; called by muse, mutect2
- CNGB3 | c.1046A>T p.Y349F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100181772, COSV60691719; called by muse, mutect2
- CNKSR1 | c.1072G>T p.A358S (on ENST00000374253 / NM_001297647.2; = p.A351S on NM_006314.3) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100836728; called by muse, mutect2, varscan2
- COL11A1 | c.3305G>C p.G1102A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100616022, COSV62188700; called by muse, mutect2, varscan2
- COL7A1 | c.1382T>A p.V461E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100095800; called by muse, mutect2, varscan2
- CPEB1 | c.995C>A p.P332H (on ENST00000617958; = p.P272H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99917602; called by muse, mutect2, varscan2
- CRACD | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1187672800, COSV99949041; called by muse, mutect2, varscan2
- CRYBB2 | c.284G>T p.S95I | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV101236728, COSV68005285; called by muse, mutect2, varscan2
- CSMD1 | c.9452G>A p.C3151Y (on ENST00000520002; = p.C3150Y on NM_033225.6) | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100146712; called by muse, mutect2, varscan2
- CSMD3 | c.10611G>C p.M3537I (on ENST00000297405 / NM_001363185.1; = p.M3368I on NM_052900.3) | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV99831444; called by muse, mutect2, varscan2
- CTNNA2 | c.1354G>T p.A452S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV100560087; called by muse, mutect2, varscan2
- CTNND2 | c.2519T>A p.M840K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV100475091; called by muse, mutect2, varscan2
- CWH43 | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56943439; called by muse, mutect2, varscan2
- CYFIP2 | c.2032G>A p.E678K (on ENST00000616178 / NM_001291722.2; = p.E653K on NM_014376.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); catalogued as COSV100556449; called by muse, varscan2
- CYLC1 | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.926); catalogued as COSV100254457; called by muse, mutect2, varscan2
- DAPK1 | c.3509G>C p.W1170S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV100801050, COSV100801601; called by muse, mutect2, varscan2
- DDX20 | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs370347142; called by muse, mutect2, varscan2
- DHX8 | c.2470A>G p.I824V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV99292141; called by muse, mutect2, varscan2
- DIO2 | c.433A>T p.K145* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV101375852; called by muse, mutect2, varscan2
- DIP2B | c.1108A>T p.T370S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99998306; called by muse, mutect2, varscan2
- DMBT1 | c.5036T>A p.L1679Q (on ENST00000338354 / NM_001377530.1; = p.L922Q on NM_004406.3) | Missense Mutation (SNP) | VAF 39/657 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100352712; called by muse, mutect2
- DMD | c.8939C>A p.A2980E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.571); catalogued as COSV58889689, COSV58945477; called by muse, mutect2, varscan2
- DMD | c.4383C>A p.F1461L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100819159; called by muse, mutect2, varscan2
- DNMT3A | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53065993; called by muse, mutect2, varscan2
- DRC7 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100395539; called by muse, mutect2, varscan2
- EAPP | c.329A>T p.D110V | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99164231; called by muse, mutect2, varscan2
- ENAM | c.1053A>T p.R351S | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV101253048; called by muse, mutect2, varscan2
- ERICH3 | c.2905G>T p.G969C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100443994; called by muse, mutect2, varscan2
- EVPL | c.1594A>C p.T532P | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV100044351; called by muse, mutect2
- EXOC4 | c.1366T>A p.Y456N | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99553405; called by muse, mutect2, varscan2
- FAM110B | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100826099, COSV64066718; called by muse, mutect2, varscan2
- FAM149A | c.971G>C p.R324T (on ENST00000356371 / NM_001367768.2; = p.R33T on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.934); catalogued as COSV99906486; called by muse, mutect2, varscan2
- FAM47A | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs1389764669, COSV100649830; called by muse, mutect2
- FAT1 | c.8689C>T p.Q2897* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as rs1169115609, COSV101499279; called by muse, mutect2, varscan2
- FAT3 | c.10224G>T p.R3408= | Splice Region (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99964792; called by muse, mutect2, varscan2
- FCGR3A | c.264G>T p.R88S | Missense Mutation (SNP) | VAF 32/461 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV100914636; called by muse, mutect2
- FIP1L1 | c.399G>T p.G133= | Splice Region (SNP) | VAF 7/71 reads (10%) | catalogued as rs750432865, COSV100184368; called by mutect2, varscan2
- FLRT2 | c.1053G>T p.R351S | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100420263; called by muse, mutect2, varscan2
- GABRA2 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100734127, COSV62916787; called by muse, mutect2, varscan2
- GABRA2 | c.301C>A p.R101S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100734130; called by muse, mutect2
- GABRA4 | c.1033A>G p.N345D | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV99973891; called by muse, mutect2, varscan2
- GATA6 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368297251; ClinVar: likely benign; called by muse, mutect2, varscan2
- GGT7 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs200005396, COSV60540825; called by muse, mutect2, varscan2
- GIGYF1 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.525); catalogued as rs1474850099, COSV99309188; called by muse, mutect2, varscan2
- GPR142 | c.694C>A p.R232S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as COSV100170775; called by muse, mutect2, varscan2
- GRHL3 | c.289G>C p.E97Q (on ENST00000350501 / NM_198174.3; = p.E102Q on NM_021180.3) | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.154); catalogued as COSV99359262; called by muse, mutect2, varscan2
- GRIN3A | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100701462; called by muse, mutect2, varscan2
- GSDME | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); catalogued as COSV100742303; called by muse, mutect2, varscan2
- H2BC14 | c.70A>T p.K24* | Nonsense Mutation (SNP) | VAF 17/127 reads (13%) | catalogued as COSV100297560; called by muse, mutect2, varscan2
- HDAC9 | c.2238C>A p.H746Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV101286697; called by muse, mutect2, varscan2
- HP1BP3 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | catalogued as COSV100391735; called by muse, mutect2, varscan2
- HS3ST2 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs935612566, COSV54462873; called by muse, mutect2, varscan2
- HSPD1 | c.766T>A p.S256T | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV100798338; called by muse, mutect2, varscan2
- IGHV3-23 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 28/357 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs1555466948; called by muse, mutect2
- ITGA6 | c.1565T>G p.L522R (on ENST00000442250; = p.L483R on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99905349; called by muse, mutect2, varscan2
- KAZALD1 | c.690G>C p.Q230H | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100930585; called by muse, mutect2, varscan2
- KCND1 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.086); catalogued as rs782744718, COSV99501891; called by mutect2, varscan2
- KDM6B | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as COSV99641179; called by muse, mutect2, varscan2
- KDM6B | c.2114C>G p.S705C | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99641185; called by muse, mutect2, varscan2
- KDR | c.2739G>T p.M913I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99817344; called by muse, mutect2, varscan2
- KHDC1 | c.316G>A p.E106K (on ENST00000370384 / NM_001251874.2; = p.E33K on NM_030568.5) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV57614796; called by muse, mutect2, varscan2
- KIAA1755 | c.2764G>T p.A922S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99641862; called by muse, mutect2, varscan2
- KIF24 | c.3421G>T p.D1141Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99903073; called by mutect2, varscan2
- KIR2DL4 | c.277C>G p.R93G (on ENST00000396284; = p.R54G on NM_001080770.2) | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100610563, COSV60877040, COSV60879620; called by muse, mutect2, varscan2
- KIR2DL4 | c.1001C>A p.P334H (on ENST00000396284; = p.P260H on NM_001080770.2) | Missense Mutation (SNP) | VAF 80/532 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs770989530, COSV58489429; called by muse, mutect2, varscan2
- KLHL42 | c.1495C>G p.L499V | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101179736; called by muse, mutect2
- KRI1 | c.812C>G p.P271R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV100470008; called by muse, mutect2, varscan2
- LARS1 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV99198555; called by muse, mutect2, varscan2
- LDB1 | c.597C>A p.F199L (on ENST00000425280 / NM_001321612.2; = p.F163L on NM_003893.5) | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV100756365; called by muse, mutect2, varscan2
- LGR4 | c.413C>A p.A138D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs536355546, COSV101004132; called by muse, varscan2
- LIX1L | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV100041206; called by muse, mutect2, varscan2
- LRP2 | c.13676C>T p.S4559F | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV99787814; called by muse, mutect2, varscan2
- LRRC8B | c.1348A>T p.I450F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100446507; called by muse, mutect2, varscan2
- LRRIQ1 | c.4927G>A p.E1643K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV101279275; called by muse, mutect2, varscan2
- LYST | c.6396A>T p.L2132F | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.845); catalogued as COSV101089059; called by muse, mutect2
- MAGEB2 | c.435C>A p.F145L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV100975640; called by muse, mutect2
- MAP2 | c.3208C>A p.L1070I | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.055); catalogued as COSV99559259; called by muse, mutect2, varscan2
- MAP4K4 | c.3145G>C p.A1049P (on ENST00000347699 / NM_001242559.2; = p.A967P on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100154312; called by muse, mutect2, varscan2
- MCHR2 | c.460A>C p.N154H | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); catalogued as COSV56002199, COSV99911864; called by muse, mutect2, varscan2
- MCOLN3 | c.395A>T p.Q132L | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100352691; called by muse, mutect2, varscan2
- MCOLN3 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 26/169 reads (15%) | catalogued as COSV100352694; called by muse, mutect2, varscan2
- MFSD6 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV99855138; called by muse, mutect2, varscan2
- MGAM | c.4936G>T p.V1646L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1384234585, COSV101527449, COSV101527797; called by muse, mutect2, varscan2
- MMP19 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100491068; called by muse, mutect2, varscan2
- MMP28 | c.426G>T p.W142C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1033851665; called by muse, mutect2, varscan2
- MRGPRX1 | c.804C>A p.N268K | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1413354726, COSV100245954; called by muse, mutect2, varscan2
- MSH4 | c.1652A>G p.D551G | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99591346; called by muse, mutect2
- MSR1 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100026979; called by muse, mutect2, varscan2
- MST1 | c.993T>G p.F331L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.615); catalogued as COSV99610711; called by muse, mutect2, varscan2
- MUC17 | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100072756; called by muse, varscan2
- MXRA5 | c.8219C>A p.T2740N | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV99476564; called by muse, mutect2, varscan2
- MYH15 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV99842986; called by muse, mutect2, varscan2
- MYH7 | c.5090G>T p.R1697L | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100805974, COSV62515973, COSV62524616; called by muse, mutect2, varscan2
- MYOF | c.3358A>T p.T1120S | Missense Mutation (SNP) | VAF 115/418 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.05); catalogued as COSV100825581; called by muse, mutect2, varscan2
- NAA11 | c.78C>A p.Y26* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV99727303; called by muse, mutect2, varscan2
- NAA40 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as rs745633405, COSV100624150; called by muse, mutect2, varscan2
- NALCN | c.4651G>T p.E1551* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV99214352; called by muse, mutect2, varscan2
- NAV3 | c.243G>A p.K81= | Splice Region (SNP) | VAF 16/41 reads (39%) | catalogued as COSV57067333, COSV99889500; called by muse, mutect2, varscan2
- NCLN | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 30/315 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as rs756499440, COSV55742863; called by muse, mutect2, varscan2
- NET1 | c.1406G>A p.R469H (on ENST00000355029 / NM_001047160.3; = p.R415H on NM_005863.5) | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as rs750957300, COSV61791302; called by muse, mutect2, varscan2
- NIBAN1 | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100836371; called by muse, mutect2, varscan2
- NID1 | c.1163A>T p.Q388L | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV99937377; called by muse, mutect2
- NOS1 | c.3860G>T p.G1287V | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100500409; called by muse, mutect2, varscan2
- NPPA | c.426C>A p.S142R | Missense Mutation (SNP) | VAF 112/672 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747448548, COSV100411828; called by muse, varscan2
- NR0B1 | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as CM074385, COSV100973505; called by muse, mutect2, varscan2
- NRP2 | c.908G>T p.R303M | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV99784090; called by muse, mutect2, varscan2
- OPCML | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as COSV100100091; called by muse, mutect2, varscan2
- OPRL1 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778663603, COSV61090978; called by muse, mutect2, varscan2
- OR14K1 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99315039, COSV99315108; called by muse, mutect2, varscan2
- OR1J2 | c.25G>T p.V9L | Missense Mutation (SNP) | VAF 71/268 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV100093203, COSV58944106; called by muse, mutect2, varscan2
- OR2A25 | c.332G>T p.C111F | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101376375; called by muse, mutect2, varscan2
- OR2A25 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as rs1230889604, COSV101376376; called by muse, mutect2
- OR2T3 | c.828C>A p.D276E | Missense Mutation (SNP) | VAF 26/565 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1464619156, COSV100613187; called by muse, mutect2
- OR4S2 | c.721del p.H241Tfs*40 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | catalogued as COSV56745558; called by mutect2, pindel, varscan2
- OR5T3 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV57380938, COSV57382707, COSV57383013; called by muse, mutect2, varscan2
- OR7C1 | c.814C>A p.L272M | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.06); catalogued as COSV99934848, COSV99934856; called by muse, mutect2, varscan2
- OR8D2 | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100658962; called by muse, mutect2, varscan2
- OTOGL | c.5763G>A p.M1921I (on ENST00000547103; = p.M1912I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 148/313 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100087125, COSV54025444; called by muse, mutect2, varscan2
- OVGP1 | c.1127A>T p.Y376F | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.05); catalogued as COSV100868093; called by muse, mutect2, varscan2
- PAPPA2 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs368485332, COSV62776395; called by muse, varscan2
- PARD3 | c.3573G>C p.Q1191H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.993); catalogued as COSV100631656; called by muse, mutect2, varscan2
- PCBP1 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.482); catalogued as COSV100340126; called by muse, mutect2, varscan2
- PCDH18 | c.3163G>T p.A1055S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs763502156, COSV100787236; called by muse, mutect2, varscan2
- PCDHB11 | c.2041G>C p.A681P | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV100696971, COSV61313362; called by muse, mutect2, varscan2
- PCDHB6 | c.1159C>A p.L387I | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.063); catalogued as COSV99170062; called by muse, mutect2
- PCDHGA9 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.216); catalogued as COSV53975095, COSV99535875; called by muse, mutect2, varscan2
- PCDHGC4 | c.1706G>T p.R569L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV52756803, COSV52776879; called by muse, mutect2, varscan2
- PELP1 | c.2128G>T p.G710C | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99342729; called by muse, mutect2, varscan2
- PKD1L1 | c.2293G>A p.V765M | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56972115; called by muse, mutect2, varscan2
- PKM | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100064561; called by mutect2, varscan2
- PLA2G4C | c.16G>T p.V6F | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100843900; called by muse, mutect2, varscan2
- PLAG1 | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1455550383, COSV100387826; called by muse, mutect2, varscan2
- PLCB4 | c.2963G>T p.G988V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV53802446, COSV99595102; called by muse, mutect2, varscan2
- POGK | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.378); catalogued as COSV100902459; called by muse, mutect2, varscan2
- PPM1D | c.471G>T p.L157= | Splice Region (SNP) | VAF 9/81 reads (11%) | catalogued as COSV100010787; called by muse, mutect2, varscan2
- PPP1R3A | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as COSV52884913, COSV99492594; called by muse, mutect2, varscan2
- PRAMEF20 | c.108del p.P38Hfs*15 | Frame Shift Del (DEL) | VAF 33/184 reads (18%) | catalogued as rs766678456; called by mutect2, pindel, varscan2
- PRDM10 | c.849G>T p.W283C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100456701; called by muse, mutect2, varscan2
- PREX2 | c.3702G>T p.Q1234H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV55799959, COSV99905404, COSV99909969; called by muse, mutect2, varscan2
- PRKG1 | c.857A>T p.E286V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV100907233; called by muse, mutect2, varscan2
- PRSS37 | c.401C>G p.S134* | Nonsense Mutation (SNP) | VAF 18/117 reads (15%) | catalogued as COSV100633835; called by muse, mutect2, varscan2
- PSAT1 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100716567, COSV99052039; called by muse, mutect2, varscan2
- PTPRT | c.3812C>A p.S1271Y | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100626614; called by muse, mutect2, varscan2
- PTPRZ1 | c.2802G>T p.E934D | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.054); catalogued as rs148162051, COSV101099937; called by muse, mutect2, varscan2
- PXDNL | c.2195G>A p.G732D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100683083; called by muse, mutect2, varscan2
- RALGDS | c.2659A>T p.K887* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100924393; called by muse, mutect2, varscan2
- RAPGEF6 | c.4532A>T p.Y1511F | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99726168; called by muse, mutect2, varscan2
- RARB | c.308G>A p.S103N (on ENST00000383772 / NM_001290216.2; = p.S96N on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100412352; called by muse, mutect2, varscan2
- RERE | c.1053C>A p.D351E | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100555884; called by muse, mutect2, varscan2
- RNMT | c.975-1G>T p.X325_splice | Splice Site (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100054577; called by muse, mutect2, varscan2
- RP1L1 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.72); catalogued as COSV101223158; called by muse, mutect2, varscan2
- RPE65 | c.1529T>C p.L510S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99253795; called by muse, mutect2, varscan2
- RPH3A | c.1744G>T p.A582S (on ENST00000389385 / NM_001143854.2; = p.A578S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.381); catalogued as COSV101231806; called by muse, mutect2, varscan2
- RPL28 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.376); catalogued as COSV100689409; called by muse, mutect2, varscan2
- RRAGC | c.1169C>A p.T390K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV100883816; called by muse, mutect2, varscan2
- RRM1 | c.64A>T p.I22F | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as COSV100331279; called by muse, mutect2, varscan2
- RYR2 | c.13840G>T p.G4614W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs936573890, COSV100769562, COSV63672474; called by muse, mutect2, varscan2
- SALL4 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 91/408 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99409434; called by muse, mutect2, varscan2
- SAMD9 | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV101180197; called by muse, mutect2, varscan2
- SCN5A | c.3230A>G p.Q1077R (on ENST00000333535 / NM_198056.3; = p.X1077_splice on NM_000335.5) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.932); catalogued as COSV100347678; called by muse, mutect2, varscan2
- SCN5A | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100347684; called by muse, mutect2, varscan2
- SERPIND1 | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV53140259, COSV99300166; called by muse, mutect2, varscan2
- SH3BGRL3 | c.147G>C p.E49D | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as COSV99432105; called by muse, mutect2, varscan2
- SIRPG | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99403659; called by muse, mutect2, varscan2
- SLC24A4 | c.293G>C p.G98A | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100104882, COSV100105159; called by muse, mutect2, varscan2
- SLC25A32 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs748296598, COSV52568075; called by muse, mutect2, varscan2
- SLC34A1 | c.1523C>A p.T508K | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99499590; called by muse, mutect2, varscan2
- SLC38A4 | c.692C>A p.T231N | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99872635; called by muse, mutect2, varscan2
- SLC66A1 | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100913211; called by muse, mutect2, varscan2
- SLFN12 | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs925152449, COSV100513010; called by muse, mutect2
- SLX4 | c.4334G>T p.R1445L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV99567906; called by muse, mutect2, varscan2
- SPATA31D1 | c.2070C>A p.H690Q | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100782708, COSV61199562; called by muse, mutect2
- SPATA7 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.085); catalogued as COSV99247894; called by muse, mutect2
- SPATC1L | c.562G>T p.G188C (on ENST00000291672 / NM_001142854.2; = p.G34C on NM_032261.5) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99385853, COSV99385914; called by muse, mutect2, varscan2
- SPTB | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 23/84 reads (27%) | catalogued as COSV101072069, COSV67633547; called by muse, varscan2
- STAB2 | c.5476C>A p.L1826I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101185873; called by muse, mutect2, varscan2
- STK11 | c.523A>T p.K175* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99045280; called by muse, mutect2, varscan2
- STK31 | c.2986G>T p.E996* | Nonsense Mutation (SNP) | VAF 10/126 reads (8%) | catalogued as COSV100669295; called by muse, mutect2
- STRIP1 | c.1333A>T p.I445L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as rs569587037, COSV100874061; called by muse, mutect2, varscan2
- STRN | c.1643C>A p.P548H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV99815167; called by muse, mutect2, varscan2
- SYNJ1 | c.1985A>G p.N662S | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs1298315820, COSV100449195; called by muse, mutect2, varscan2
- TAAR6 | c.462C>A p.S154R | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.465); catalogued as COSV99256604; called by muse, mutect2, varscan2
- TAF5 | c.596G>C p.S199T | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as COSV100674648; called by muse, mutect2, varscan2
- TBC1D32 | c.2105C>T p.A702V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as rs1377038144, COSV99250043; called by muse, mutect2, varscan2
- TCF4 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100610066; called by muse, mutect2
- TCHH | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.067); catalogued as rs1200172563, COSV64273147, COSV64274723; called by muse, mutect2, varscan2
- TECRL | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101168756, COSV67090861; called by muse, mutect2, varscan2
- TECTA | c.2810G>T p.R937L | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50741830, COSV50779559; called by muse, mutect2, varscan2
- TFDP1 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as COSV100945807; called by muse, mutect2, varscan2
- THNSL1 | c.2031G>T p.Q677H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100896167; called by muse, mutect2, varscan2
- THSD7B | c.1479G>T p.W493C | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99744102, COSV99748569; called by muse, mutect2, varscan2
- TICAM1 | c.356A>C p.Q119P | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV99941074; called by muse, mutect2, varscan2
- TKT | c.1569G>C p.K523N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as COSV99964972; called by muse, mutect2, varscan2
- TMC4 | c.875G>T p.S292I (on ENST00000617472 / NM_001145303.3; = p.S286I on NM_144686.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000462; called by muse, mutect2, varscan2
- TRIM58 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100825033, COSV100825307; called by muse, mutect2, varscan2
- TRPV5 | c.443C>G p.T148R | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV99520364; called by muse, mutect2, varscan2
- TSNAX | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100791093; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 20/162 reads (12%) | catalogued as COSV99535001; called by muse, mutect2, varscan2
- TSPYL2 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.42); catalogued as COSV100212196, COSV60238252; called by muse, mutect2
- VCL | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.935); catalogued as COSV99280695; called by muse, mutect2, varscan2
- XPO6 | c.2137C>T p.R713* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV58970262; called by muse, mutect2, varscan2
- ZFHX4 | c.8002G>T p.V2668L | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV51466963, COSV51506078; called by muse, mutect2, varscan2
- ZFHX4 | c.8347A>G p.N2783D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); catalogued as COSV99261389; called by muse, mutect2, varscan2
- ZHX2 | c.785T>A p.L262Q | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100072882; called by muse, mutect2, varscan2
- ZIM3 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV99075110; called by muse, mutect2
- ZMYM1 | c.97-1G>T p.X33_splice | Splice Site (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100720954; called by muse, mutect2
- ZNF131 | c.17C>G p.T6R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.298); catalogued as COSV100185379; called by muse, mutect2, varscan2
- ZNF233 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.171); catalogued as COSV61934769; called by muse, mutect2, varscan2
- ZNF420 | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100421278; called by muse, mutect2, varscan2
- ZNF423 | c.3317G>T p.R1106L (on ENST00000563137 / NM_001379286.1; = p.R1098L on NM_015069.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as COSV99281069; called by muse, mutect2, varscan2
- ZNF445 | c.2817G>C p.L939F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV101253739; called by muse, mutect2, varscan2
- ZNF611 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100160202, COSV60540893; called by muse, mutect2, varscan2
- ZNF774 | c.531G>T p.R177S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100586292; called by muse, mutect2, varscan2
- ZNF808 | c.1779A>T p.K593N | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV100707881; called by muse, mutect2, varscan2
- ZNF81 | c.1426G>T p.G476W | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100095254; called by muse, mutect2, varscan2
- ZNF81 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV100095540; called by muse, mutect2, varscan2
- ZSWIM2 | c.808del p.H270Tfs*16 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | catalogued as COSV54575299; called by mutect2, pindel, varscan2
- ADAMTS7 | c.3941C>T p.T1314I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); called by mutect2, varscan2
- ADGRL4 | c.1547_1548del p.Y516Sfs*49 | Frame Shift Del (DEL) | VAF 18/152 reads (12%) | called by mutect2, pindel, varscan2
- ALG1 | c.510del p.N171Tfs*21 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.6518_6522del p.H2173Rfs*44 | Frame Shift Del (DEL) | VAF 2/18 reads (11%) | called by mutect2, varscan2
- CD9 | c.354del p.K119Rfs*14 | Frame Shift Del (DEL) | VAF 43/274 reads (16%) | called by mutect2, pindel, varscan2
- FCGBP | c.2608C>A p.P870T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, varscan2
- KIR3DL2 | c.485A>G p.E162G | Missense Mutation (SNP) | VAF 75/330 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- KRTAP10-4 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- LYZL6 | c.156T>A p.F52L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- OR6V1 | c.202del p.E68Rfs*4 | Frame Shift Del (DEL) | VAF 37/272 reads (14%) | called by mutect2, pindel, varscan2
- ZNF658 | c.1250G>A p.C417Y | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, varscan2
- AASDH | c.972A>G p.S324= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as rs145602652; called by muse, mutect2, varscan2
- AASDHPPT | c.297G>A p.S99= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV53788290, COSV99593323; called by muse, mutect2, varscan2
- ABCA3 | c.3225C>T p.S1075= | Silent (SNP) | VAF 22/194 reads (11%) | catalogued as COSV100068325; called by muse, mutect2, varscan2
- ADAMTS12 | c.2682C>T p.C894= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV61276428; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.990C>T p.I330= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as COSV100416392; called by muse, mutect2, varscan2
- ADGRG4 | c.6699G>A p.S2233= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as rs1281865179, COSV54966068; called by muse, mutect2, varscan2
- AQP11 | c.141C>T p.F47= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1014665348, COSV100547355; called by muse, mutect2, varscan2
- ATP1B3 | c.462C>T p.C154= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as COSV99657246; called by muse, mutect2, varscan2
- C9orf64 | c.846G>T p.S282= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV100123556; called by muse, mutect2
- CDH9 | c.393A>T p.I131= | Silent (SNP) | VAF 18/248 reads (7%) | catalogued as COSV99143328; called by muse, mutect2
- CHD4 | c.3507G>A p.E1169= (on ENST00000357008 / NM_001363606.2; = p.E1182= on NM_001273.5) | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV100537773; called by muse, mutect2, varscan2
- DHX38 | c.3663G>T p.T1221= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV99194279; called by muse, mutect2, varscan2
- ELAPOR1 | c.1563C>A p.T521= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV100884426; called by muse, mutect2, varscan2
- EPG5 | c.3114T>C p.C1038= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs1213183628, COSV99957011; called by muse, mutect2, varscan2
- FAT1 | c.1089G>T p.G363= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV101499280; called by muse, mutect2, varscan2
- FBXL7 | c.1053C>A p.R351= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100309559, COSV61653062; called by muse, mutect2, varscan2
- FDXR | c.1461C>G p.R487= (on ENST00000293195 / NM_024417.5; = p.R493= on NM_004110.6) | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV99500863; called by muse, mutect2, varscan2
- FOXB1 | c.951C>G p.S317= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV101249755; called by muse, mutect2
- GLYATL1 | c.885C>T p.Y295= (on ENST00000317391 / NM_001354699.1; = p.Y326= on NM_080661.4) | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100265270; called by muse, mutect2, varscan2
- GRK6 | c.141C>T p.L47= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100586871; called by muse, mutect2, varscan2
- H2BC14 | c.69G>A p.Q23= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as COSV100297559; called by muse, mutect2, varscan2
- H3C10 | c.127C>A p.R43= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV100297558, COSV60797553; called by muse, mutect2
- HAO1 | c.360A>G p.E120= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV101113185; called by muse, mutect2, varscan2
- HDLBP | c.1689G>T p.V563= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV100190336; called by muse, mutect2, varscan2
- HHAT | c.1221G>A p.E407= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99803668; called by muse, mutect2
- HUWE1 | c.5601C>A p.I1867= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99471713; called by muse, mutect2, varscan2
- INO80D | c.2244G>T p.L748= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV101305813; called by muse, mutect2, varscan2
- IQGAP2 | c.2751T>A p.T917= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99167028; called by muse, mutect2
- KANSL1 | c.2053C>T p.L685= | Silent (SNP) | VAF 20/197 reads (10%) | catalogued as COSV99294375; called by muse, mutect2, varscan2
- KCNG4 | c.387C>A p.A129= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100377019, COSV57583210; called by muse, mutect2, varscan2
- KCNH1 | c.864C>G p.R288= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV99658605; called by muse, mutect2
- KCNK13 | c.513G>T p.L171= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV99965625; called by muse, mutect2, varscan2
- LRP4 | c.3684C>T p.A1228= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs375095757, COSV101066383; called by mutect2, varscan2
- LSM14A | c.651T>C p.P217= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV101471681; called by muse, mutect2, varscan2
- MARCHF8 | c.444G>T p.T148= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV100165701; called by muse, mutect2, varscan2
- MARVELD3 | c.483G>A p.E161= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV99194817; called by muse, mutect2
- MTNR1A | c.591C>A p.L197= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as COSV100208178, COSV56155542; called by muse, mutect2, varscan2
- NOD1 | c.261C>G p.L87= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV99767980; called by muse, mutect2
- NTSR2 | c.747C>G p.S249= | Silent (SNP) | VAF 40/209 reads (19%) | catalogued as COSV100183871; called by muse, mutect2, varscan2
- OGDHL | c.1332C>A p.S444= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as COSV100934131, COSV100934250; called by muse, mutect2, varscan2
- OR10A4 | c.528C>T p.N176= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV101139490; called by muse, mutect2, varscan2
- OR14I1 | c.423G>A p.Q141= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as COSV100700465; called by muse, mutect2, varscan2
- OR1E1 | c.297C>T p.T99= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs774513651, COSV100491911; called by muse, mutect2, varscan2
- PAX2 | c.1113G>T p.P371= (on ENST00000428433 / NM_003987.5; = p.P348= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV100695125, COSV62292360; called by muse, mutect2, varscan2
- PCYT1A | c.990C>A p.P330= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs371440341, CD140080, COSV99492060; called by muse, mutect2, varscan2
- PDPR | c.912C>T p.G304= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs781243674, COSV55350651; called by muse, mutect2, varscan2
- PEX5L | c.783C>T p.S261= | Silent (SNP) | VAF 51/96 reads (53%) | catalogued as COSV99828434; called by muse, mutect2, varscan2
- PLEKHH3 | c.429G>A p.G143= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV53188862, COSV99511911; called by muse, mutect2, varscan2
- PRDM7 | c.465T>A p.P155= | Silent (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- PRPSAP1 | c.339G>A p.L113= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV100221693; called by muse, mutect2, varscan2
- PSG11 | c.717A>T p.P239= | Silent (SNP) | VAF 73/238 reads (31%) | catalogued as COSV100105719; called by muse, mutect2, varscan2
- PTPRB | c.5241C>A p.S1747= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV99716963; called by muse, mutect2, varscan2
- PYDC2 | c.84T>A p.S28= | Silent (SNP) | VAF 89/160 reads (56%) | catalogued as COSV101573357; called by muse, mutect2, varscan2
- RIMS2 | c.2964C>T p.V988= (on ENST00000666250 / NM_001348490.2; = p.V796= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as COSV99166585; called by muse, mutect2, varscan2
- RNF213 | c.14502C>G p.S4834= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100300290; called by muse, mutect2, varscan2
- RTL8C | c.48C>T p.I16= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as COSV57060028; called by muse, mutect2, varscan2
- SCN10A | c.4713C>A p.L1571= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV101479356; called by muse, mutect2, varscan2
- SEL1L2 | c.15T>C p.S5= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as COSV99430082; called by muse, mutect2, varscan2
- SLC13A2 | c.420C>T p.S140= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV100120279; called by muse, mutect2, varscan2
- SLC24A3 | c.864C>T p.S288= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV100040689; called by muse, mutect2, varscan2
- SLC29A3 | c.1149G>T p.V383= | Silent (SNP) | VAF 61/209 reads (29%) | catalogued as COSV100928459; called by muse, mutect2, varscan2
- SP4 | c.1830T>A p.S610= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99754323; called by muse, mutect2, varscan2
- SPTA1 | c.2320C>A p.R774= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV100934740; called by muse, mutect2, varscan2
- ST6GAL2 | c.1497G>A p.T499= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs766315603, COSV62417769; called by muse, mutect2, varscan2
- SUPT20HL1 | c.840G>A p.E280= | Silent (SNP) | VAF 17/131 reads (13%) | called by muse, mutect2, varscan2
- TM4SF1 | c.513A>G p.G171= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV100542979; called by muse, mutect2, varscan2
- TMEM168 | c.2019G>A p.L673= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100454595; called by muse, mutect2, varscan2
- TMEM169 | c.672C>A p.S224= | Silent (SNP) | VAF 61/157 reads (39%) | catalogued as COSV99824466; called by muse, mutect2, varscan2
- TRIM58 | c.840T>A p.P280= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100825034; called by muse, mutect2, varscan2
- TRPC5 | c.2082C>T p.R694= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV53305161, COSV99460427; called by muse, mutect2, varscan2
- TTK | c.576G>A p.K192= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs1053416082, COSV57886241; called by muse, mutect2, varscan2
- UGT2B11 | c.1440C>A p.A480= | Silent (SNP) | VAF 41/262 reads (16%) | catalogued as COSV71423286; called by muse, mutect2, varscan2
- USH2A | c.4074A>T p.G1358= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as COSV100232977, COSV100243171; called by muse, mutect2, varscan2
- VSX2 | c.663C>A p.L221= | Silent (SNP) | VAF 29/192 reads (15%) | catalogued as COSV100001575; called by muse, mutect2, varscan2
- VWF | c.5646G>A p.E1882= | Silent (SNP) | VAF 38/275 reads (14%) | catalogued as rs758463173, COSV99778749; called by muse, mutect2, varscan2
- WDSUB1 | c.1206A>C p.S402= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100701814; called by muse, mutect2, varscan2
- ZNF93 | c.166C>T p.L56= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as COSV100652246; called by muse, mutect2, varscan2
- ZNFX1 | c.2193A>G p.E731= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100870807; called by muse, mutect2
- ACOX1 | c.431-2700G>T | Intron (SNP) | VAF 13/62 reads (21%) | catalogued as rs753668223, COSV53131915, COSV53134137; called by muse, mutect2, varscan2
- BRD1 | c.*2G>T | 3'UTR (SNP) | VAF 49/425 reads (12%) | catalogued as rs1168216430, COSV53461214, COSV99349604; called by muse, mutect2, varscan2
- LINC01098 | n.752C>T | RNA (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.250-9082G>T | Intron (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99790654; called by muse, varscan2
- MGAM | c.4618+5612C>T | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as COSV101527448; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397430 A>G | 3'Flank (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442495 T>C | 3'Flank (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100678892; called by muse, mutect2
- PRRG3 | c.-1C>A | 5'UTR (SNP) | VAF 21/75 reads (28%) | catalogued as COSV100948605; called by muse, mutect2, varscan2
- TCP10L3 | n.613A>G | RNA (SNP) | VAF 16/248 reads (6%) | catalogued as COSV100833056; called by muse, mutect2
